Somatic mutation profile of tumor specimen TCGA-G5-6235-01A (aliquot TCGA-G5-6235-01A-11D-1733-10) from TCGA case TCGA-G5-6235, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.1 years (26,348 days).
Specimen TCGA-G5-6235-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f32bfce3-c1ef-410a-b5ce-83029a55459f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G5-6235-10A (Blood Derived Normal), aliquot TCGA-G5-6235-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4376c565-6a24-47dc-9428-45d2d18a6433

The open-access MAF lists 123 somatic variants for this specimen: 103 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 19, Nonsense Mutation 6, Frame Shift Ins 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 24/79 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs1567556930, COSV52694020, COSV53536519; ClinVar: pathogenic; called by muse, mutect2
- ABCA12 | c.1232G>C p.R411P (on ENST00000272895 / NM_173076.3; = p.R93P on NM_015657.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV55947659, COSV99790235; called by mutect2, varscan2
- ADGRV1 | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 25/256 reads (10%) | catalogued as COSV101316067; called by muse, mutect2, varscan2
- AHNAK | c.3215T>C p.V1072A | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1386392272, COSV57226310; called by muse, mutect2, varscan2
- ARHGAP21 | c.5872C>A p.L1958I | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57610027; called by muse, mutect2, varscan2
- ASAP3 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV60873374; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52877118; called by muse, mutect2
- BARHL1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs763702971, COSV55038709; called by muse, mutect2, varscan2
- CBLL2 | c.416A>T p.K139M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.157); catalogued as COSV60370010; called by muse, mutect2, varscan2
- CBY2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60119502; called by muse, mutect2, varscan2
- CCDC73 | c.1622T>C p.L541S | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV58803380; called by muse, mutect2, varscan2
- CEMIP2 | c.3772C>T p.R1258C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs374049571; called by muse, mutect2, varscan2
- CEP350 | c.8450T>C p.L2817S | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs746683315, COSV62608500; called by muse, mutect2, varscan2
- CFAP77 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.319); catalogued as rs370319315, COSV100546200; called by muse, mutect2, varscan2
- CHD6 | c.2362A>T p.I788F | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100498332; called by muse, mutect2, varscan2
- CHRD | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768399856, COSV52611557; called by muse, mutect2, varscan2
- CILP2 | c.3181G>A p.V1061I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375471099; called by muse, mutect2, varscan2
- CLASP1 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV55336200; called by muse, mutect2, varscan2
- COL22A1 | c.3979G>T p.G1327C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100278757; called by muse, mutect2
- COL5A3 | c.4702G>A p.A1568T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1279804523, COSV53409689; called by muse, varscan2
- COPS3 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs749417297, COSV52006980; called by muse, mutect2, varscan2
- CPB1 | c.719A>G p.H240R | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1489213965, COSV99294345; called by muse, mutect2, varscan2
- CSAD | c.1330C>T p.R444C (on ENST00000444623 / NM_001244705.2; = p.R471C on NM_015989.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs374597733, COSV99914805; called by muse, mutect2, varscan2
- CSNK1A1L | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.029); catalogued as rs375626846; called by muse, mutect2, varscan2
- DIP2B | c.845A>T p.N282I | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56590260; called by muse, mutect2, varscan2
- DNAH1 | c.3878A>G p.D1293G | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101325992; called by muse, mutect2, varscan2
- DOCK10 | c.3001A>T p.M1001L | Missense Mutation (SNP) | VAF 46/340 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV51424953; called by muse, mutect2, varscan2
- DSCAM | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs374471813; called by muse, varscan2
- DSCAML1 | c.1033C>T p.R345W (on ENST00000321322; = p.R285W on NM_020693.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs868719705, COSV58390499; called by muse, mutect2
- DYSF | c.4757G>A p.R1586Q | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs538781815, COSV99243789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECI1 | c.900A>C p.E300D | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100065816; called by muse, mutect2, varscan2
- EPG5 | c.1389G>T p.L463F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56354744; called by muse, mutect2, varscan2
- FAM135B | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV52747605, COSV99426212; called by muse, mutect2, varscan2
- FAM184A | c.1072C>A p.H358N | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); catalogued as COSV58857709; called by muse, mutect2, varscan2
- FAT3 | c.8032G>A p.V2678I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53160805; called by muse, mutect2, varscan2
- FBXL7 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61650133; called by muse, mutect2
- FBXO41 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV54588392; called by muse, mutect2, varscan2
- FER1L6 | c.1649C>G p.P550R | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV67548859, COSV67552195; called by muse, varscan2
- FNDC1 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as rs770479635, COSV51945671; called by muse, mutect2, varscan2
- FREM2 | c.6832C>T p.R2278C | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375661157; called by muse, mutect2, varscan2
- GCSAML | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs747408807, COSV63577121, COSV63577142; called by muse, mutect2, varscan2
- GNL1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV64835490; called by muse, mutect2, varscan2
- GSTA2 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV72415419; called by muse, mutect2, varscan2
- HDAC7 | c.1027C>T p.R343W (on ENST00000427332; = p.R382W on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs1025523835, COSV50405745; called by muse, mutect2, varscan2
- HDLBP | c.2347G>A p.V783I | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs761469892, COSV60497343; called by muse, mutect2, varscan2
- HDX | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52980157; called by muse, mutect2, varscan2
- HEPHL1 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59895375; called by muse, mutect2
- JPT1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764477731, COSV55470736; called by muse, varscan2
- KHDC4 | c.543T>G p.I181M | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV64165562; called by muse, mutect2
- KLHL1 | c.2190G>T p.M730I | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV64780412; called by muse, mutect2
- LAMB2 | c.3818C>T p.T1273I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV100026215; called by muse, mutect2
- LAMB4 | c.3975T>G p.I1325M | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV52728417; called by muse, mutect2, varscan2
- LCA5L | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 25/202 reads (12%) | catalogued as COSV55746969; called by muse, mutect2, varscan2
- LMNB2 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs777408921, COSV53115154; called by muse, mutect2, varscan2
- LOXL4 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs199557224; called by muse, mutect2, varscan2
- LRGUK | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138421011, COSV53634221; called by muse, mutect2, varscan2
- LRP2 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.06); catalogued as rs548624353, COSV55574384; called by muse, mutect2, varscan2
- LRRK2 | c.3152C>T p.P1051L | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100110348; called by muse, mutect2, varscan2
- MTNR1B | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.16); catalogued as rs150570442; called by muse, mutect2, varscan2
- MYH7B | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs369138767; called by muse, varscan2
- NF1 | c.3855G>T p.M1285I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV62216499; called by muse, mutect2, varscan2
- NHLH2 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV57202789, COSV57202957; called by muse, mutect2, varscan2
- NLRP11 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV64085969; called by muse, mutect2, varscan2
- NTRK3 | c.2083A>T p.I695F | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV62307012, COSV62313108; called by muse, mutect2
- OBSCN | c.12112C>T p.R4038C | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs373344634; called by muse, mutect2, varscan2
- OR10H1 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1256912974, COSV100612423, COSV58471652; called by muse, mutect2, varscan2
- OR2A5 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV68739041; called by muse, mutect2, varscan2
- OR2A5 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV68739043; called by muse, mutect2, varscan2
- OR2A5 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV68739046; called by muse, mutect2, varscan2
- OR2AK2 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV100823777, COSV63550957; called by muse, mutect2, varscan2
- OR51I1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV66508934; called by muse, mutect2, varscan2
- PCDHGA7 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as rs757654723, COSV53916545; called by muse, mutect2, varscan2
- PDZD4 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV51250024; called by muse, mutect2, varscan2
- PKDREJ | c.2989G>T p.V997F | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV53552182; called by muse, mutect2
- PPIAL4G | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs1465167332, COSV101343997; called by muse, mutect2
- PPP6R2 | c.2513C>T p.A838V (on ENST00000216061 / NM_001365836.1; = p.A804V on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs765052205, COSV53292989; called by muse, mutect2, varscan2
- PRAMEF17 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 68/493 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as COSV101068738; called by muse, mutect2, varscan2
- PRR15L | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99846515; called by muse, mutect2
- PSD2 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753531914, COSV51207904, COSV51212681; called by muse, mutect2, varscan2
- RASGRP2 | c.813+2T>A p.X271_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV62450601; called by muse, mutect2, varscan2
- RCBTB2 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV100749593; called by muse, mutect2
- RHEX | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs782267753, COSV58980322; called by muse, mutect2, varscan2
- RNASE13 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs549619794, COSV58795466; called by muse, mutect2, varscan2
- RNF157 | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV99487032; called by muse, mutect2, varscan2
- ROM1 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV99605947; called by muse, mutect2, varscan2
- SDK1 | c.4084G>A p.G1362R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746987893, COSV67384777; called by muse, mutect2, varscan2
- SLCO4A1 | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV99414791; called by muse, mutect2, varscan2
- SMARCAD1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); catalogued as COSV100758946; called by muse, mutect2
- TDRD1 | c.315_316insC p.P107Afs*12 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | catalogued as COSV99314611, COSV99314891; called by mutect2, pindel, varscan2
- TDRD1 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.352); catalogued as COSV99314614; called by muse, mutect2, varscan2
- TMEM72 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369873974, COSV101273604; called by muse, mutect2, varscan2
- TNS3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388960310, COSV60789674; called by muse, mutect2, varscan2
- TPSG1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.444); catalogued as rs760566430, COSV52357407; called by muse, mutect2, varscan2
- TTN | c.45595C>G p.P15199A (on ENST00000591111; = p.P7775A on NM_003319.4) | Missense Mutation (SNP) | VAF 37/235 reads (16%) | PolyPhen benign (0.245); catalogued as COSV59891460; called by muse, mutect2, varscan2
- UBA7 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61093311; called by muse, mutect2, varscan2
- ZDBF2 | c.6038C>A p.S2013Y | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65629162, COSV65630039; called by muse, mutect2, varscan2
- ZNF521 | c.3067G>A p.V1023M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456911942, COSV64130829; called by muse, mutect2, varscan2
- ALOX15B | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2
- SYNRG | c.3218G>C p.S1073T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRIM24 | c.2433dup p.P812Tfs*12 (on ENST00000343526 / NM_015905.3; = p.P778Tfs*12 on NM_003852.4) | Frame Shift Ins (INS) | VAF 19/153 reads (12%) | called by mutect2, pindel, varscan2
- ALDH18A1 | c.990A>C p.G330= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV64663373, COSV64663463; called by muse, mutect2, varscan2
- HFM1 | c.3105C>T p.D1035= | Silent (SNP) | VAF 37/279 reads (13%) | catalogued as rs748543481, COSV54036743, COSV99646149; called by muse, mutect2, varscan2
- KCNB1 | c.660C>T p.F220= | Silent (SNP) | VAF 25/232 reads (11%) | catalogued as rs751017425, COSV65566922, COSV65568775; called by muse, mutect2
- KRT35 | c.1296C>T p.C432= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs367703815; called by muse, mutect2, varscan2
- NISCH | c.3057G>T p.T1019= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100617268, COSV61901770; called by muse, mutect2, varscan2
- OR5M1 | c.108A>T p.L36= | Silent (SNP) | VAF 42/278 reads (15%) | catalogued as COSV73202102; called by muse, mutect2, varscan2
- OXSR1 | c.1422C>T p.V474= | Silent (SNP) | VAF 29/255 reads (11%) | catalogued as rs758209525, COSV61257920; called by muse, mutect2, varscan2
- PCDHA4 | c.1452G>T p.A484= | Silent (SNP) | VAF 39/199 reads (20%) | catalogued as rs782266582, COSV100793514, COSV63542602; called by muse, mutect2, varscan2
- PCSK1 | c.51C>T p.C17= | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as rs774807858, COSV60733605; called by muse, mutect2, varscan2
- PCSK2 | c.1119C>T p.Y373= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs538265087, COSV52741092; called by muse, mutect2, varscan2
- SMAD9 | c.228C>T p.D76= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs938475620, COSV63204091; called by muse, mutect2, varscan2
- SYT3 | c.603G>T p.L201= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100144137; called by muse, mutect2
- TENT5D | c.225C>T p.H75= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV57638686; called by muse, mutect2, varscan2
- TERT | c.2793C>T p.C931= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs764925909, COSV57228211; ClinVar: likely benign; called by mutect2, varscan2
- TRIB3 | c.828G>A p.G276= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs746757202, COSV53932378; called by muse, mutect2, varscan2
- VPS52 | c.1470C>T p.S490= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs750596630, COSV71403607; called by muse, mutect2, varscan2
- WIPI1 | c.765G>T p.T255= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV50931249; called by muse, mutect2, varscan2
- ZMAT2 | c.444G>A p.E148= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1266848642, COSV51227377; called by muse, mutect2, varscan2
- ZNF274 | c.75G>A p.P25= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs567797622, COSV100465143; called by muse, mutect2, varscan2
- ZSCAN21 | c.*225C>T | 3'UTR (SNP) | VAF 17/149 reads (11%) | catalogued as rs1161568207, COSV52851319; called by muse, mutect2, varscan2
